Somatic mutation profile of tumor specimen MBCProject_0381_T2_WES (aliquot MBCProject_0381_T2_WES_1) from CMI case MBCProject_0381, project CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project. Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 46.0 years (16,805 days).
Specimen MBCProject_0381_T2_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Breast; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3769ed44-1426-4f26-ac73-812254e70b09.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MBCProject_0381_SALIVA (Saliva), aliquot MBCProject_0381_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6f80e303-aaa5-42c0-ae04-e561fa945ee1

The open-access MAF lists 17 somatic variants for this specimen: 13 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 12, Silent 4, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDH1 | c.1198G>A p.D400N | Missense Mutation (SNP) | VAF 26/118 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55735735, COSV55745602; called by muse, mutect2, varscan2
- HIPK4 | c.1343A>G p.N448S | Missense Mutation (SNP) | VAF 13/119 reads (11%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as rs367871526; called by muse, mutect2, varscan2
- KATNIP | c.367C>T p.R123W | Missense Mutation (SNP) | VAF 28/187 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as rs187220970; called by muse, mutect2, varscan2
- PEX7 | c.689A>G p.N230S | Missense Mutation (SNP) | VAF 13/241 reads (5%) | SIFT tolerated (0.2); PolyPhen benign (0.084); catalogued as rs984236887; called by muse, mutect2
- SCN5A | c.1366G>A p.V456M | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.818); catalogued as rs760016062, COSV61126272; ClinVar: uncertain significance; called by mutect2, varscan2
- SSB | c.358A>G p.T120A | Missense Mutation (SNP) | VAF 8/87 reads (9%) | SIFT tolerated (0.68); PolyPhen benign (0.001); catalogued as rs757444172; called by mutect2, varscan2
- THAP4 | c.347C>T p.S116L | Missense Mutation (SNP) | VAF 12/108 reads (11%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.019); catalogued as rs773405275; called by muse, mutect2, varscan2
- ZDHHC5 | c.1240A>G p.K414E | Missense Mutation (SNP) | VAF 11/150 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.191); catalogued as rs1270219692; called by muse, mutect2
- ZNF142 | c.5341C>T p.R1781C (on ENST00000411696 / NM_001379660.1; = p.R1581C on NM_001105537.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/140 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.034); catalogued as rs370225990; called by muse, mutect2, varscan2
- ASTN1 | c.2753C>T p.S918L | Missense Mutation (SNP) | VAF 20/258 reads (8%) | SIFT tolerated (0.37); PolyPhen benign (0); called by muse, mutect2
- ESF1 | c.825_845del p.D275_D281del | In Frame Del (DEL) | VAF 18/114 reads (16%) | called by mutect2, varscan2
- OR7D4 | c.817A>G p.T273A | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0); called by mutect2, varscan2
- XKR7 | c.1371G>T p.K457N | Missense Mutation (SNP) | VAF 11/100 reads (11%) | SIFT tolerated (0.44); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- KLRG1 | c.318A>G p.R106= | Silent (SNP) | VAF 9/101 reads (9%) | called by muse, mutect2
- RBAK | c.846T>C p.A282= | Silent (SNP) | VAF 13/122 reads (11%) | called by muse, mutect2, varscan2
- RTEL1 | c.1557C>G p.G519= | Silent (SNP) | VAF 14/168 reads (8%) | called by muse, mutect2
- ZNF785 | c.93C>T p.F31= | Silent (SNP) | VAF 12/62 reads (19%) | catalogued as COSV67876272, COSV67876546; called by muse, mutect2, varscan2
